Somatic mutation profile of tumor specimen TCGA-22-0944-01A (aliquot TCGA-22-0944-01A-01D-1521-08) from TCGA case TCGA-22-0944, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 61.1 years (22,329 days).
Specimen TCGA-22-0944-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef542aa8-03c0-4163-be84-d990e5c05cd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-0944-11A (Solid Tissue Normal), aliquot TCGA-22-0944-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53dd03b5-808d-44e6-86b6-4f5f2b82bb2c

The open-access MAF lists 131 somatic variants for this specimen: 93 protein-altering or splice-affecting, 34 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 34, Nonsense Mutation 7, Intron 3, Frame Shift Del 3, Frame Shift Ins 1, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 38/79 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.4171T>A p.C1391S | Missense Mutation (SNP) | VAF 53/291 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100711573, COSV61265839; called by muse, mutect2, varscan2
- AHCYL2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV61488119; called by muse, mutect2, varscan2
- AKNAD1 | c.289A>T p.I97F | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV62199562; called by muse, mutect2, varscan2
- AP1G1 | c.932A>G p.N311S | Missense Mutation (SNP) | VAF 85/275 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV55490812; called by muse, mutect2, varscan2
- ASXL1 | c.4099G>A p.V1367I | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147456014; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ1B | c.1327A>G p.M443V | Missense Mutation (SNP) | VAF 77/312 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs1369392556, COSV59991914; called by muse, mutect2, varscan2
- BCL2L14 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866608585, COSV53789161; called by muse, mutect2, varscan2
- BMPR1A | c.587A>T p.D196V | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV64406566; called by muse, mutect2, varscan2
- CCDC136 | c.2245G>A p.G749S | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV52800779, COSV99922678; called by muse, mutect2, varscan2
- CCDC181 | c.1318G>A p.E440K (on ENST00000367806 / NM_001300969.1; = p.E439K on NM_021179.2) | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV61393937; called by muse, mutect2, varscan2
- CCNY | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 85/362 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs201763356, COSV55186162; called by muse, mutect2, varscan2
- CDH16 | c.1394C>A p.P465H | Missense Mutation (SNP) | VAF 113/173 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV55337241; called by muse, mutect2, varscan2
- CDH20 | c.1916T>A p.I639N | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV53011796; called by muse, mutect2, varscan2
- CDH6 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54071928, COSV54076421; called by muse, mutect2, varscan2
- CECR2 | c.2494C>T p.R832* (on ENST00000342247 / NM_001290047.2; = p.R649* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 24/135 reads (18%) | catalogued as COSV52843326; called by muse, mutect2, varscan2
- CKMT2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs548849398, COSV54172310; called by muse, mutect2
- CLN8 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV58670826; called by muse, mutect2, varscan2
- CMTR2 | c.467A>C p.H156P | Missense Mutation (SNP) | VAF 190/309 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57603683; called by muse, mutect2, varscan2
- CNGA4 | c.1552C>A p.L518M | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as COSV101171858, COSV66006259; called by muse, mutect2, varscan2
- CNTNAP4 | c.2249C>A p.T750N | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs368916686, COSV56685755; called by muse, mutect2, varscan2
- CNTNAP5 | c.409A>C p.S137R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV70491150; called by muse, mutect2, varscan2
- CSF1 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as COSV60033880; called by muse, mutect2
- CSMD3 | c.5996G>T p.G1999V (on ENST00000297405 / NM_001363185.1; = p.G1895V on NM_052900.3) | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV52211083, COSV52286393; called by muse, mutect2, varscan2
- DCAF10 | c.538G>T p.G180W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54289160; called by muse, mutect2, varscan2
- DCAF4L2 | c.541del p.Q181Rfs*12 | Frame Shift Del (DEL) | VAF 66/257 reads (26%) | catalogued as COSV60479840; called by mutect2, pindel, varscan2
- DNM1L | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 84/294 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56775100; called by muse, mutect2, varscan2
- EDAR | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV51504485, COSV99303586; called by muse, mutect2
- ERCC6L2 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 9/169 reads (5%) | catalogued as COSV56631566, COSV56633407; called by muse, mutect2
- FAM217B | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.929); catalogued as COSV62564568; called by muse, mutect2, varscan2
- FAT3 | c.8792G>T p.G2931V | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53125955; called by muse, mutect2, varscan2
- FLI1 | c.908A>T p.E303V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55645432; called by muse, mutect2, varscan2
- FLNC | c.6682C>T p.R2228W | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs1196014760, COSV57957722, COSV57964509; called by muse, mutect2, varscan2
- FLOT2 | c.1097A>T p.Q366L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV101204736, COSV67529144; called by muse, mutect2
- FSIP2 | c.20260A>T p.M6754L | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV58089234; called by muse, mutect2, varscan2
- GPRASP1 | c.2668G>T p.G890* | Nonsense Mutation (SNP) | VAF 99/155 reads (64%) | catalogued as COSV64355863; called by muse, mutect2, varscan2
- GRIA1 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.313); catalogued as COSV53608082, COSV53627746; called by muse, mutect2, varscan2
- GRM1 | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51172606; called by muse, mutect2, varscan2
- HIVEP3 | c.2155A>T p.K719* | Nonsense Mutation (SNP) | VAF 58/103 reads (56%) | catalogued as COSV56017149; called by muse, mutect2, varscan2
- IFNGR2 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV51639917; called by muse, mutect2, varscan2
- KLHL1 | c.175A>C p.S59R | Missense Mutation (SNP) | VAF 75/130 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.104); catalogued as COSV64774506; called by muse, mutect2, varscan2
- LRP1B | c.7999G>T p.D2667Y | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67234405; called by muse, mutect2, varscan2
- LRPPRC | c.2707A>T p.N903Y | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV53239643, COSV99581452; called by muse, mutect2, varscan2
- LRRC25 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs769281545, COSV59115315; called by muse, mutect2, varscan2
- MAGI1 | c.2699C>T p.A900V (on ENST00000402939 / NM_001033057.2; = p.A928V on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs200362587, COSV58318552; called by muse, mutect2, varscan2
- MARCKS | c.499A>T p.S167C | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64042887; called by muse, mutect2, varscan2
- MARK3 | c.1373G>T p.S458I | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV53511500; called by muse, mutect2, varscan2
- MORC3 | c.2794C>A p.Q932K | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV68688500; called by muse, mutect2, varscan2
- MYO3A | c.722A>C p.K241T | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56335150; called by muse, mutect2, varscan2
- NAV3 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 102/263 reads (39%) | catalogued as COSV57087520; called by muse, mutect2, varscan2
- NLRC3 | c.410C>A p.P137Q | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.985); catalogued as COSV100072773; called by muse, mutect2, varscan2
- NOL4 | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.201); catalogued as rs1301908551, COSV52350401; called by muse, mutect2, varscan2
- NRXN1 | c.3392G>C p.G1131A | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as COSV58438772, COSV58462079; called by muse, mutect2
- OR1Q1 | c.445C>A p.H149N | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV52918275; called by muse, mutect2, varscan2
- OR2AG2 | c.495C>A p.H165Q | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.034); catalogued as COSV58455455, COSV58455517; called by muse, mutect2, varscan2
- OR52B2 | c.143T>A p.I48K | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV73209431; called by muse, mutect2, varscan2
- PASD1 | c.1238C>G p.P413R | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV64855765; called by muse, mutect2
- PCDHGA1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 13/321 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65297178; called by muse, mutect2
- PM20D1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs1255981949, COSV65649095; called by muse, mutect2, varscan2
- PRCP | c.1208G>T p.R403M | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57289365; called by muse, mutect2, varscan2
- PRKD1 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 202/330 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV59573091; called by muse, mutect2, varscan2
- PSMC5 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV56740051; called by muse, mutect2, varscan2
- PTPRM | c.1861T>C p.Y621H | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59864670; called by muse, mutect2, varscan2
- RP1 | c.4430A>T p.D1477V | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV55119112; called by muse, mutect2, varscan2
- RPTN | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 71/613 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV60167597; called by muse, mutect2, varscan2
- RYR2 | c.12688G>C p.G4230R | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV63686396, COSV63691636; called by muse, mutect2, varscan2
- SATB1 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV58667948, COSV58670095; called by muse, mutect2, varscan2
- SETBP1 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.961); catalogued as COSV56325898; called by muse, mutect2, varscan2
- SH3GL2 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66051431; called by muse, mutect2, varscan2
- SIPA1L1 | c.2453A>T p.E818V | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62170961; called by muse, mutect2, varscan2
- SLC35G5 | c.401G>C p.R134P | Missense Mutation (SNP) | VAF 94/366 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.503); catalogued as COSV55313117; called by muse, varscan2
- SLC7A14 | c.2148C>A p.S716R | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV51583946; called by muse, mutect2
- SRGAP2 | c.1877C>T p.S626L (on ENST00000624873 / NM_001170637.4; = p.S627L on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55339009; called by muse, varscan2
- TAS2R41 | c.758A>G p.D253G | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.296); catalogued as COSV68765453; called by muse, mutect2, varscan2
- TBC1D10C | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as COSV56703327; called by muse, mutect2, varscan2
- TECTA | c.5867G>A p.R1956Q | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs780312128, COSV50724657; called by muse, mutect2, varscan2
- TENM3 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV69311040; called by muse, mutect2, varscan2
- TLR5 | c.627T>G p.Y209* | Nonsense Mutation (SNP) | VAF 15/177 reads (8%) | catalogued as rs776525523, COSV60558898, COSV60559452; called by muse, mutect2
- TNS3 | c.1921G>C p.V641L | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as COSV60792915; called by muse, mutect2, varscan2
- TRAF6 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV61922730; called by muse, varscan2
- TRPA1 | c.3243T>A p.D1081E | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51562455, COSV51564412; called by muse, mutect2, varscan2
- TUBA3D | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 156/290 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.074); catalogued as COSV58312113; called by muse, mutect2, varscan2
- WBP11 | c.156G>C p.Q52H | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53763390, COSV99660929; called by muse, mutect2, varscan2
- WDR45 | c.851G>A p.G284E (on ENST00000376372 / NM_001029896.2; = p.G285E on NM_007075.3) | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV59876278; called by muse, mutect2, varscan2
- XYLB | c.888G>T p.A296= | Splice Region (SNP) | VAF 55/113 reads (49%) | catalogued as COSV52913966; called by muse, mutect2, varscan2
- ZBTB49 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV61925296; called by muse, mutect2, varscan2
- ZNF665 | c.1498A>C p.T500P (on ENST00000600412; = p.T565P on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV67215730; called by muse, mutect2, varscan2
- ZNF721 | c.1598A>G p.Y533C (on ENST00000338977; = p.Y545C on NM_133474.4) | Missense Mutation (SNP) | VAF 113/237 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs782005709, COSV59093674; called by muse, mutect2, varscan2
- ITGA10 | c.1438dup p.E480Gfs*10 | Frame Shift Ins (INS) | VAF 19/86 reads (22%) | called by mutect2, pindel, varscan2
- PGR | c.211_218delinsTGTCCCT p.D71Cfs*3 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | called by pindel, varscan2*
- SPATA31A3 | c.762G>T p.L254F | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.274); called by mutect2, varscan2
- UNC45A | c.1890_1898del p.S630_V632del | In Frame Del (DEL) | VAF 21/187 reads (11%) | called by mutect2, pindel, varscan2
- ZFR2 | c.2092del p.R698Gfs*6 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | called by mutect2, pindel, varscan2
- ARHGAP31 | c.1371G>C p.S457= | Silent (SNP) | VAF 73/222 reads (33%) | catalogued as COSV51789804, COSV51794480; called by muse, mutect2, varscan2
- ATP1A1 | c.1992A>T p.V664= | Silent (SNP) | VAF 94/189 reads (50%) | catalogued as COSV55191951; called by muse, mutect2, varscan2
- B2M | c.108G>A p.E36= | Silent (SNP) | VAF 37/335 reads (11%) | catalogued as COSV62563143, COSV62564821; called by muse, mutect2, varscan2
- CHFR | c.1935G>A p.V645= (on ENST00000432561 / NM_001161345.1; = p.V604= on NM_018223.2) | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV57175416; called by muse, mutect2, varscan2
- CKMT2 | c.213C>A p.A71= | Silent (SNP) | VAF 52/115 reads (45%) | catalogued as COSV54173763; called by muse, mutect2
- CNGA2 | c.786G>T p.R262= | Silent (SNP) | VAF 118/175 reads (67%) | catalogued as COSV61705012; called by muse, mutect2, varscan2
- COL15A1 | c.1551C>G p.P517= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV66646216; called by muse, mutect2, varscan2
- CSMD3 | c.9162G>T p.G3054= (on ENST00000297405 / NM_001363185.1; = p.G2885= on NM_052900.3) | Silent (SNP) | VAF 46/155 reads (30%) | catalogued as COSV52211050; called by muse, mutect2, varscan2
- DTX1 | c.1059C>G p.A353= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV57498468, COSV57500819; called by muse, mutect2, varscan2
- DYSF | c.4725C>G p.P1575= | Silent (SNP) | VAF 35/296 reads (12%) | catalogued as COSV50451631; called by muse, mutect2, varscan2
- FANCA | c.2127G>T p.P709= | Silent (SNP) | VAF 100/280 reads (36%) | catalogued as COSV66881996, COSV66882448; called by muse, mutect2, varscan2
- GIMAP8 | c.1761T>A p.L587= | Silent (SNP) | VAF 75/248 reads (30%) | catalogued as COSV56232181; called by muse, mutect2, varscan2
- GLI3 | c.2769C>T p.P923= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs761730228, COSV67889878; called by muse, mutect2, varscan2
- IGHV1-46 | c.93G>A p.K31= | Silent (SNP) | VAF 10/228 reads (4%) | catalogued as rs1555524859; called by muse, mutect2
- IGLJ7 | c.46G>T p.*16= | Silent (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2
- L1CAM | c.603C>T p.S201= | Silent (SNP) | VAF 79/113 reads (70%) | catalogued as rs782223025, COSV62828583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LILRB3 | c.573G>A p.R191= | Silent (SNP) | VAF 53/129 reads (41%) | catalogued as rs1207055668; called by muse, mutect2, varscan2
- LRFN5 | c.567G>A p.G189= | Silent (SNP) | VAF 42/81 reads (52%) | catalogued as COSV53261249; called by muse, mutect2, varscan2
- LRRN3 | c.726T>G p.S242= | Silent (SNP) | VAF 73/199 reads (37%) | catalogued as COSV57820892; called by muse, mutect2, varscan2
- LRRTM4 | c.729C>T p.S243= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV69139993; called by muse, mutect2, varscan2
- NT5DC2 | c.549G>A p.Q183= | Silent (SNP) | VAF 54/135 reads (40%) | catalogued as rs773483301, COSV58738081; called by muse, mutect2, varscan2
- OR1L4 | c.891T>C p.D297= | Silent (SNP) | VAF 56/139 reads (40%) | catalogued as COSV52340279; called by muse, mutect2, varscan2
- OVCH1 | c.2094T>C p.C698= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV58964479; called by muse, mutect2, varscan2
- PARD3B | c.3609A>G p.A1203= (on ENST00000406610 / NM_001302769.2; = p.A1134= on NM_057177.7) | Silent (SNP) | VAF 74/151 reads (49%) | catalogued as rs1231266269, COSV62515389; called by muse, mutect2, varscan2
- PDE1A | c.307C>A p.R103= | Silent (SNP) | VAF 126/350 reads (36%) | catalogued as rs1252203134, COSV59515352, COSV59526039; called by muse, mutect2, varscan2
- PLVAP | c.384C>T p.N128= | Silent (SNP) | VAF 40/268 reads (15%) | catalogued as rs1568375687, COSV53085807; called by muse, varscan2
- PTPRF | c.375C>G p.L125= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs768382559, COSV63445965; called by muse, mutect2, varscan2
- RD3 | c.51C>T p.S17= | Silent (SNP) | VAF 49/186 reads (26%) | catalogued as rs1234982419, COSV65362436; called by muse, varscan2
- SLC35G5 | c.402C>T p.R134= | Silent (SNP) | VAF 94/368 reads (26%) | catalogued as COSV55313122; called by muse, varscan2
- SLC6A2 | c.696G>T p.L232= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as rs768200271, COSV54917802; called by muse, varscan2
- SMYD2 | c.144G>T p.R48= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV65291091; called by muse, mutect2, varscan2
- ST8SIA5 | c.153G>T p.G51= | Silent (SNP) | VAF 86/274 reads (31%) | catalogued as rs745497654, COSV59332747; called by muse, mutect2, varscan2
- UTP20 | c.5542C>T p.L1848= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV55378997; called by muse, mutect2, varscan2
- ZNF276 | c.405C>G p.V135= (on ENST00000443381 / NM_001113525.2; = p.V60= on NM_152287.4) | Silent (SNP) | VAF 56/188 reads (30%) | catalogued as COSV57069464; called by muse, mutect2, varscan2
- ADARB2 | c.101-147719G>T | Intron (SNP) | VAF 24/263 reads (9%) | catalogued as COSV101184488; called by muse, mutect2
- ADGRA1 | c.256-389A>G | Intron (SNP) | VAF 11/21 reads (52%) | catalogued as COSV101192694; called by muse, mutect2, varscan2
- ASPH | c.323-11701G>T | Intron (SNP) | VAF 45/179 reads (25%) | catalogued as COSV100727552; called by muse, mutect2, varscan2
- SNORD115-33 | n.12G>A | RNA (SNP) | VAF 37/391 reads (9%) | catalogued as rs1166134334; called by muse, mutect2
